Gene-level copy-number profile of tumor specimen C3L-03497-54 from CPTAC case C3L-03497, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.0 years (21,911 days).
Specimen C3L-03497-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bda2a547-18e8-4f9a-a537-eb0c918fd0d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03497-51 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,680 have no estimate.
https://portal.gdc.cancer.gov/files/751d02e0-2722-4854-ad53-587af645c73b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,132; copy number 1: 7,258; copy number 2: 42,107; copy number 3: 4,813; copy number 4: 873; copy number 5: 634; copy number 6: 491; copy number 7: 284; copy number 8: 121; copy number 9: 80; copy number 10: 44; copy number 11: 21; copy number 12: 9; copy number 13: 14; copy number 14: 13; copy number 15: 7; copy number 16: 4; copy number 17: 3; copy number 18: 1; copy number 19: 9; copy number 20: 4; copy number 22: 3; copy number 23: 1; copy number 24: 1; copy number 25: 1; copy number 27: 2; copy number 28: 1; copy number 30: 3; copy number 33: 1; copy number 43: 1; copy number 46: 1; copy number 50: 2; copy number 53: 1; copy number 54: 1; copy number 115: 1; copy number 558: 1.

Homozygous deletions (total copy number 0; autosomes only): 1,132 genes in 588 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,974,356–35,031,945, 5 genes: AC114490.3, AC114490.1, AC114490.2, TMEM35B, ZMYM6.
- chr1:43,389,882–43,456,995, 5 genes: SZT2, SZT2-AS1, MIR6735, HYI, HYI-AS1.
- chr1:171,083,565–171,117,819, 4 genes: BX284613.1, FMO3, MIR1295A, MIR1295B.
- chr2:74,421,678–74,533,332, 18 genes (within-gene range 0–3): WDR54, RTKN, INO80B, INO80B-WBP1, WBP1, MOGS, AC005041.5, MRPL53, CCDC142, TTC31, LBX2, AC005041.3, LBX2-AS1, PCGF1, TLX2, DQX1, AUP1, HTRA2.
- chr2:89,009,982–89,872,702, 37 genes (within-gene range 0–2): IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV1D-39, IGKV2D-38.
- chr2:89,913,982–89,969,335, 7 genes: IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27.
- chr2:90,082,635–90,221,384, 11 genes: IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr2:178,521,183–178,830,802, 10 genes (within-gene range 0–2): TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1.
- chr2:219,229,783–219,278,170, 5 genes (within-gene range 0–2): ANKZF1, GLB1L, STK16, TUBA4A, TUBA4B.
- chr7:26,533,121–27,024,907, 5 genes: KIAA0087, AC004947.2, AC004947.1, LINC02860, TPM3P4.
- chr7:27,184,507–27,193,448, 8 genes (within-gene range 0–6): HOXA11-AS, AC004080.7, AC004080.14, AC004080.8, AC004080.2, AC004080.12, AC004080.15, AC004080.13.
- chr7:97,851,677–97,972,985, 5 genes (within-gene range 0–4): ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29.
- chr7:97,946,987–97,972,254, 6 genes: OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1.
- chr8:43,251,711–43,284,806, 5 genes: AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4.
- chr8:144,495,458–144,525,172, 6 genes (within-gene range 0–1): AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14.
- chr10:73,082,494–73,169,055, 6 genes (within-gene range 0–1): Y_RNA, AL731563.3, NUDT13, AC016394.1, SNORA11F, ECD.
- chr10:101,570,560–101,609,662, 4 genes: DPCD, POLL, MIR3158-1, MIR3158-2.
- chr10:103,389,041–103,452,402, 5 genes (within-gene range 0–1): ATP5MD, MIR1307, PDCD11, CALHM2, AL139339.2.
- chr11:48,263,861–48,366,465, 5 genes: OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5.
- chr11:55,291,883–55,389,472, 7 genes: TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P.
- chr11:55,554,307–55,686,160, 9 genes: OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.
- chr11:56,097,244–56,205,625, 12 genes: OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1.
- chr11:56,315,144–56,376,553, 7 genes: OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1.
- chr11:58,358,124–58,428,121, 5 genes: OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2.
- chr11:71,538,025–71,603,353, 8 genes (within-gene range 0–7): KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P.
- chr12:56,076,799–56,163,496, 12 genes (within-gene range 0–7): ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6.
- chr12:56,316,223–56,362,857, 5 genes (within-gene range 0–1): PAN2, IL23A, STAT2, RNU7-40P, APOF.
- chr12:82,358,528–82,515,817, 5 genes (within-gene range 0–3): METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1.
- chr15:42,800,968–43,116,493, 5 genes (within-gene range 0–3): KRT8P50, FDPSP4, UBR1, AC068724.2, RPS3AP47.
- chr15:43,593,054–43,699,222, 10 genes: CKMT1B, STRC, RNU6-554P, AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2, AC011330.1, CKMT1A.
- chr15:43,772,605–43,804,427, 6 genes (within-gene range 0–1): ELL3, AC018512.1, SERF2, MIR1282, SERINC4, HYPK.
- chr15:69,391,192–69,448,427, 5 genes (within-gene range 0–7): AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1.
- chr16:23,670,011–23,713,226, 6 genes (within-gene range 0–2): AC008870.1, PLK1, AC008870.3, ERN2, AC008870.5, AC012317.1.
- chr17:656,794–792,509, 8 genes (within-gene range 0–4): RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4.
- chr17:4,967,995–4,988,446, 6 genes (within-gene range 0–1): AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2.
- chr17:10,383,132–10,657,309, 8 genes (within-gene range 0–5): AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3.
- chr17:29,972,514–30,069,631, 5 genes (within-gene range 0–1): AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2.
- chr17:41,346,092–41,440,983, 8 genes (within-gene range 0–1): KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38.
- chr20:35,626,031–35,674,544, 5 genes (within-gene range 0–1): CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12.
- chr20:45,534,196–45,547,752, 5 genes: WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,760 genes in 808 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,556,087–24,844,321, 6 genes, copy number 5–7: NCMAP, AL445686.1, Y_RNA, SRRM1, CLIC4, RNU6-1208P.
- chr1:29,329,620–30,141,607, 6 genes, copy number 5–18: LINC01756, AL671862.1, AC092265.1, AL645944.1, LINC01648, AL137076.1.
- chr1:116,423,724–116,571,039, 6 genes, copy number 6–7 (within-gene range 1–7): LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2, CD58.
- chr1:204,562,413–204,707,430, 6 genes, copy number 5–7: RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75.
- chr2:37,820,498–38,239,590, 11 genes, copy number 5–7 (within-gene range 2–7): LINC00211, RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12.
- chr2:59,014,354–60,439,828, 14 genes, copy number 5–7 (within-gene range 1–7): AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432.
- chr2:104,406,471–104,722,966, 8 genes, copy number 5–8 (within-gene range 3–8): AC068535.1, LINC01831, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1.
- chr2:120,542,905–121,182,580, 9 genes, copy number 5–11: AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1.
- chr3:71,567,863–71,785,206, 7 genes, copy number 5–13 (within-gene range 4–13): AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2.
- chr4:6,995,341–7,068,064, 6 genes, copy number 5–20 (within-gene range 4–20): AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1.
- chr4:11,469,250–12,641,009, 8 genes, copy number 5–9: AC025539.1, AC005699.1, LINC02360, AC108037.1, LINC02270, RNU6-578P, ECM1P2, AC093809.1.
- chr4:157,879,902–158,111,931, 6 genes, copy number 5–7: AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3.
- chr5:1,877,413–2,737,759, 9 genes, copy number 5–20: IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC126768.1, Y_RNA, AC092266.1, LSINCT5, AC091891.1.
- chr5:4,012,708–4,866,311, 6 genes, copy number 5–6 (within-gene range 2–12): AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1.
- chr5:14,872,332–15,384,853, 7 genes, copy number 5–12: AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5.
- chr5:17,604,177–17,649,643, 10 genes, copy number 6: TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5.
- chr5:100,021,804–100,055,045, 11 genes, copy number 7: Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22.
- chr7:897,900–1,138,260, 11 genes, copy number 5: ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1.
- chr8:33,580,210–34,346,731, 9 genes, copy number 5–7 (within-gene range 0–11): RN7SL621P, DUSP26, BUD31P1, RN7SL457P, VENTXP5, AF279873.1, AF279873.4, AC087855.2, AC090993.1.
- chr9:117,643,151–118,083,382, 8 genes, copy number 5–6: AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9.
- chr9:126,270,121–126,885,878, 12 genes, copy number 5–16: AL162391.2, MVB12B, NRON, SNORD116, AL356309.2, AL356309.3, AL356309.1, AL161908.1, LMX1B, AL161908.2, ZBTB43, ZBTB34.
- chr10:1,159,768–2,081,097, 9 genes, copy number 6–8 (within-gene range 2–13): LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, LINC00700, AL441943.1, MIR6072.
- chr10:43,385,617–43,525,217, 6 genes, copy number 5–8 (within-gene range 5–19): HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2.
- chr10:127,867,881–128,085,855, 6 genes, copy number 6–14: BUB1P1, CLRN3, PTPRE, AL158166.2, AL158166.1, AL390236.1.
- chr10:128,958,772–129,770,983, 6 genes, copy number 6–9 (within-gene range 2–9): AL355537.1, AL391869.1, MGMT, AL355531.1, AL157832.2, AL157832.1.
- chr11:58,579,063–58,731,974, 7 genes, copy number 6–9 (within-gene range 0–9): ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1.
- chr11:70,467,856–71,252,577, 7 genes, copy number 5 (within-gene range 4–14): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:125,132,847–125,592,568, 7 genes, copy number 5–9 (within-gene range 2–9): AP001007.2, PKNOX2-AS1, PKNOX2, AP001007.3, AP001007.1, RNU6-321P, FEZ1.
- chr11:130,159,782–130,403,657, 6 genes, copy number 5–7: ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT.
- chr12:124,513,222–124,638,444, 10 genes, copy number 5–11 (within-gene range 5–13): AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4.
- chr12:131,165,011–131,455,436, 11 genes, copy number 5–19: LINC01257, AC126564.1, RPS6P20, AC092850.1, LINC02415, RNA5SP376, LINC02370, AC140118.2, AC140118.1, AC073578.4, AC073578.2.
- chr13:43,879,284–44,240,517, 7 genes, copy number 5–9 (within-gene range 0–10): LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1, LINC00390, SMIM2-AS1.
- chr13:52,167,709–52,341,896, 6 genes, copy number 6–7: MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333.
- chr16:24,208,105–24,495,177, 6 genes, copy number 5–7: AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1.
- chr16:51,150,770–51,525,157, 6 genes, copy number 6–8 (within-gene range 1–8): AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1.
- chr17:30,090,366–30,252,237, 11 genes, copy number 5–7 (within-gene range 1–8): AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5, SLC6A4, AC104984.1, AC104984.4, SNORD63.
- chr19:29,220,864–29,526,948, 8 genes, copy number 5–10 (within-gene range 1–10): AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4.
- chr20:21,499,261–21,703,585, 8 genes, copy number 5–30: AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1.
- chr22:48,044,710–48,898,386, 10 genes, copy number 5–8 (within-gene range 5–18): FP325330.1, FP325330.2, BX284656.2, BX284656.1, MIR3201, Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310.
- chr22:49,264,201–49,739,003, 10 genes, copy number 5–25: Z82202.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1, RN7SKP252.

Autosomal genes at a single copy (total copy number 1): 4,914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
